Somatic mutation profile of tumor specimen MP2PRT-PAVAXA-TMP1-A (aliquot MP2PRT-PAVAXA-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVAXA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,318 days).
Specimen MP2PRT-PAVAXA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8467b2b2-6c4d-4efd-990d-fd195376e0d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAXA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAXA-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/734b6b35-a576-4bcb-a552-789f1ccee5e7

The open-access MAF lists 42 somatic variants for this specimen: 25 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 16, Frame Shift Ins 2, Nonsense Mutation 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/322 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 91/359 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 89/426 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, mutect2, varscan2
- PTPN11 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 46/363 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDADC1 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs143438894; called by muse, mutect2, varscan2
- CYBC1 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 111/561 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139347006; called by muse, mutect2, varscan2
- EBF3 | c.833G>T p.G278V (on ENST00000355311 / NM_001375392.1; = p.G269V on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/493 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290100150; called by mutect2, varscan2
- MYLPF | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 87/443 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs144209299; called by muse, mutect2, varscan2
- TENM3 | c.4726C>T p.R1576* | Nonsense Mutation (SNP) | VAF 17/480 reads (4%) | catalogued as rs866549816, COSV69311360; called by muse, mutect2
- THSD7B | c.3817C>T p.R1273W (on ENST00000272643; = p.R1271W on NM_001316349.2) | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200780753; called by muse, mutect2, varscan2
- TM9SF4 | c.1859C>T p.T620M | Missense Mutation (SNP) | VAF 101/506 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1481100172, COSV54111580; called by muse, mutect2, varscan2
- TRPC7 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 85/665 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1274493309, COSV61452394; called by muse, mutect2, varscan2
- WDR12 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 52/366 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs1191685509; called by muse, mutect2, varscan2
- ASCL5 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 213/638 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC138 | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EPN2 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 68/596 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN3 | c.7847dup p.R2617Tfs*6 | Frame Shift Ins (INS) | VAF 141/681 reads (21%) | called by mutect2, pindel, varscan2
- FOXF2 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 254/922 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGKJ5 | c.1_2insCCCG p.I2Pfs*13 | Frame Shift Ins (INS) | VAF 30/178 reads (17%) | called by mutect2, pindel, varscan2
- IL1RL1 | c.39G>C p.M13I | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1210 | c.3205A>G p.T1069A | Missense Mutation (SNP) | VAF 155/611 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LDLR | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 111/572 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGEL2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 174/780 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- YTHDC2 | c.2599C>T p.R867* | Nonsense Mutation (SNP) | VAF 104/450 reads (23%) | called by muse, mutect2, varscan2
- ZNF236 | c.3017C>T p.S1006F | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASR | c.960C>T p.F320= | Silent (SNP) | VAF 60/463 reads (13%) | catalogued as rs753011255, COSV56133741; ClinVar: likely benign; called by muse, mutect2, varscan2
- DENND4B | c.2835G>A p.G945= | Silent (SNP) | VAF 118/738 reads (16%) | called by muse, mutect2, varscan2
- DOCK9 | c.4257G>A p.L1419= (on ENST00000376460 / NM_001366676.2; = p.L1420= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/337 reads (8%) | called by muse, mutect2
- FAM53A | c.273G>A p.P91= | Silent (SNP) | VAF 165/623 reads (26%) | catalogued as rs1316656959, COSV57403888; called by muse, mutect2, varscan2
- GIGYF1 | c.66G>A p.V22= | Silent (SNP) | VAF 87/527 reads (17%) | catalogued as COSV99309786; called by muse, mutect2, varscan2
- HAUS7 | c.753G>A p.E251= | Silent (SNP) | VAF 48/608 reads (8%) | called by muse, mutect2
- IGKV1D-8 | chr2:90221383 CCCAC>AGG | Silent (DEL) | VAF 33/50 reads (66%) | called by pindel, varscan2*
- LIPT1 | c.256C>T p.L86= | Silent (SNP) | VAF 65/304 reads (21%) | called by muse, mutect2, varscan2
- NTM | c.15G>A p.Q5= | Silent (SNP) | VAF 193/418 reads (46%) | catalogued as COSV66296233; called by muse, mutect2, varscan2
- PEAK1 | c.3177G>A p.R1059= | Silent (SNP) | VAF 71/366 reads (19%) | catalogued as COSV56933302; called by muse, mutect2, varscan2
- RLBP1 | c.258G>A p.E86= | Silent (SNP) | VAF 112/744 reads (15%) | catalogued as COSV51528817; called by muse, mutect2, varscan2
- RORC | c.18G>A p.Q6= | Silent (SNP) | VAF 115/712 reads (16%) | called by muse, mutect2, varscan2
- SERPINA4 | c.519C>T p.Y173= | Silent (SNP) | VAF 85/426 reads (20%) | catalogued as rs764068417, COSV54069007; called by muse, mutect2, varscan2
- SMIM10L2B | c.36G>A p.A12= | Silent (SNP) | VAF 100/572 reads (17%) | called by mutect2, varscan2
- SYNE1 | c.20730G>T p.L6910= (on ENST00000367255 / NM_182961.4; = p.L6839= on NM_033071.3) | Silent (SNP) | VAF 42/192 reads (22%) | called by muse, mutect2, varscan2
- TRIM50 | c.720C>T p.F240= | Silent (SNP) | VAF 53/438 reads (12%) | called by muse, mutect2, varscan2
- TRAV5 | chr14:21749705 ins GGGGACC | 3'Flank (INS) | VAF 44/205 reads (21%) | called by mutect2, pindel*, varscan2
